Somatic mutation profile of tumor specimen MMRF_2775_1_BM_CD138pos (aliquot MMRF_2775_1_BM_CD138pos_T1_KHS5U_L15724) from MMRF case MMRF_2775, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2775_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3fd6efb-00c9-42cd-b3b4-1921ddad6b92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2775_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2775_1_PB_WBC_C2_KHS5U_L15768; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc6178c3-a141-47e5-a9f7-e23621994bcc

The open-access MAF lists 40 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 9, Intron 5, Silent 4, RNA 2, Splice Site 2, 5'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP1A1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.947); catalogued as rs367709511, COSV65696821; called by muse, mutect2, varscan2
- DDX5 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56749041; called by muse, mutect2, varscan2
- FAT3 | c.10368+1G>A p.X3456_splice | Splice Site (SNP) | VAF 43/153 reads (28%) | catalogued as rs746557008, COSV53116976; called by muse, mutect2, varscan2
- FMN2 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142687; called by muse, mutect2
- HOXC11 | c.819C>G p.D273E | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV54534419; called by muse, mutect2, varscan2
- IGKJ5 | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 89/205 reads (43%) | catalogued as rs371804051; called by muse, varscan2
- IGKV1-33 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs763981784; called by muse, varscan2
- MORN3 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1555325467; called by muse, mutect2, varscan2
- NRXN1 | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1453129845; called by muse, mutect2, varscan2
- PCLO | c.11759C>A p.S3920* | Nonsense Mutation (SNP) | VAF 59/137 reads (43%) | catalogued as COSV61648472; called by muse, varscan2
- TMEM41B | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1402986931; called by muse, mutect2, varscan2
- ARHGAP17 | c.93+2T>A p.X31_splice | Splice Site (SNP) | VAF 28/48 reads (58%) | called by muse, varscan2
- MAMDC2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NFAT5 | c.3364A>T p.T1122S | Missense Mutation (SNP) | VAF 133/291 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.11893C>A p.Q3965K | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, varscan2
- RARS2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- RUBCN | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VMO1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2
- AC069544.2 | c.1056T>C p.L352= | Silent (SNP) | VAF 115/231 reads (50%) | called by muse, mutect2, varscan2
- GJA1 | c.705C>T p.G235= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as rs746726971, COSV56996990; called by muse, mutect2, varscan2
- MPND | c.480C>T p.A160= | Silent (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- PLP1 | c.480C>G p.T160= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100393548; called by muse, mutect2, varscan2
- AJUBA | c.*913T>C | 3'UTR (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2
- CCNYL2 | n.927T>C | RNA (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- EIF5 | c.*2389T>A | 3'UTR (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- IL21R | c.-17+524C>T | Intron (SNP) | VAF 71/145 reads (49%) | catalogued as rs768851710; called by muse, mutect2, varscan2
- LINC01517 | n.177C>T | RNA (SNP) | VAF 105/317 reads (33%) | called by muse, mutect2, varscan2
- LRRC8D | c.-72G>C | 5'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- MAF1 | c.*435T>C | 3'UTR (SNP) | VAF 70/134 reads (52%) | called by muse, mutect2, varscan2
- NNMT | c.*652C>G | 3'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- PHF13 | c.*672G>C | 3'UTR (SNP) | VAF 71/163 reads (44%) | called by muse, mutect2, varscan2
- PLA2G6 | c.894+82A>T | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- PLA2G6 | c.894+81G>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as rs565135800; called by muse, mutect2, varscan2
- PPP3R2 | c.*1149C>T | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- SERBP1 | c.*571_*572del | 3'UTR (DEL) | VAF 30/73 reads (41%) | catalogued as rs1228744402; called by mutect2, pindel, varscan2
- TMSB4X | chrX:12975423 T>C | 5'Flank (SNP) | VAF 78/87 reads (90%) | catalogued as rs760989274; called by muse, mutect2, varscan2
- TPRG1 | c.*1563del | 3'UTR (DEL) | VAF 56/168 reads (33%) | catalogued as rs1014663222; called by mutect2, varscan2
- TSNAX | c.367+15G>C | Intron (SNP) | VAF 67/159 reads (42%) | called by muse, mutect2, varscan2
- UBE2E1 | c.484+117T>G | Intron (SNP) | VAF 21/71 reads (30%) | catalogued as rs772233218; called by muse, mutect2, varscan2
- ZNF493 | c.*976T>A | 3'UTR (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
